Somatic mutation profile of tumor specimen MBCProject_0068_T1_WES (aliquot MBCProject_0068_T1_WES_1) from CMI case MBCProject_0068, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 36.9 years (13,463 days).
Specimen MBCProject_0068_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 14c52cc0-fe00-4588-b579-c1bc34454965.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_0068_SALIVA (Saliva), aliquot MBCProject_0068_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6d6b8be6-57c6-4cd1-ad99-a4a46b388cc9

The open-access MAF lists 69 somatic variants for this specimen: 51 protein-altering or splice-affecting, 12 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 47, Silent 12, Intron 5, Nonsense Mutation 3, Splice Region 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.836G>A p.G279E | Missense Mutation (SNP) | VAF 71/305 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1064793881, COSV52677880, COSV52851240; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCD1 | c.1142G>A p.R381H | Missense Mutation (SNP) | VAF 22/205 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs782755297, COSV54383879; ClinVar: likely benign; called by muse, mutect2, varscan2
- ANKRD44 | c.793G>A p.V265M | Missense Mutation (SNP) | VAF 22/239 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs368929104; called by muse, mutect2, varscan2
- ARHGAP40 | c.1787G>A p.R596H | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.825); catalogued as rs758427564, COSV54805212; called by muse, mutect2, varscan2
- CD1D | c.836G>T p.C279F | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1316027050; called by muse, mutect2
- GEMIN5 | c.2630G>C p.R877T | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs1288889238, COSV53565426; called by mutect2, varscan2
- H3C4 | c.214G>C p.V72L | Missense Mutation (SNP) | VAF 28/225 reads (12%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.031); catalogued as rs892619198, COSV61912209; called by muse, mutect2, varscan2
- HBS1L | c.1523A>T p.K508I | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63200990; called by muse, mutect2, varscan2
- HDAC4 | c.808C>T p.R270C | Missense Mutation (SNP) | VAF 54/161 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs371367857; called by muse, mutect2, varscan2
- KCNMA1 | c.1501G>T p.E501* | Nonsense Mutation (SNP) | VAF 16/334 reads (5%) | catalogued as COSV54278995; called by muse, mutect2
- KRT78 | c.1469C>T p.S490F | Missense Mutation (SNP) | VAF 23/178 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.96); catalogued as rs1358300590; called by muse, mutect2, varscan2
- MYH1 | c.3418C>T p.R1140C | Missense Mutation (SNP) | VAF 42/195 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1432611647, COSV56848015; called by muse, mutect2, varscan2
- NSFL1C | c.47C>T p.T16M | Missense Mutation (SNP) | VAF 24/199 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as rs1277892030; called by muse, mutect2, varscan2
- OR51V1 | c.241G>C p.V81L | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT tolerated (1); PolyPhen possibly damaging (0.612); catalogued as COSV58316667; called by muse, mutect2, varscan2
- PCDHB8 | c.1415G>T p.G472V | Missense Mutation (SNP) | VAF 30/859 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.971); catalogued as COSV99177166; called by muse, mutect2
- PCDHGA7 | c.1528G>A p.D510N | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.072); catalogued as rs1385986483; called by muse, mutect2, varscan2
- PLCZ1 | c.1290G>A p.M430I | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT tolerated (0.81); PolyPhen possibly damaging (0.472); catalogued as COSV99856715; called by muse, mutect2, varscan2
- PREX2 | c.124C>G p.L42V | Missense Mutation (SNP) | VAF 13/190 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.199); catalogued as COSV55754535; called by muse, mutect2
- RASA1 | c.550G>A p.G184R | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV57196958; called by muse, mutect2, varscan2
- TMEM39B | c.851G>A p.W284* | Nonsense Mutation (SNP) | VAF 16/122 reads (13%) | catalogued as rs1321468369; called by muse, mutect2, varscan2
- URGCP | c.1969G>T p.G657W (on ENST00000453200 / NM_001077663.3; = p.G648W on NM_017920.4) | Missense Mutation (SNP) | VAF 58/273 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56248392; called by muse, mutect2, varscan2
- ADAMTS6 | c.211C>T p.R71W | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- AQP7 | c.926C>A p.P309H | Missense Mutation (SNP) | VAF 6/122 reads (5%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); called by muse, mutect2
- C19orf54 | c.248A>G p.E83G | Missense Mutation (SNP) | VAF 35/289 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.395); called by muse, mutect2, varscan2
- CMTM6 | c.245G>A p.S82N | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); called by muse, mutect2, varscan2
- CROCC | c.1790C>A p.A597D | Missense Mutation (SNP) | VAF 21/300 reads (7%) | SIFT tolerated (0.33); PolyPhen benign (0.079); called by muse, mutect2
- CYP4A11 | c.1255C>T p.H419Y | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- DHCR24 | c.13G>A p.V5M | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.134); called by muse, varscan2
- DHX9 | c.3757A>T p.R1253W | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.624); called by muse, varscan2
- DNAH7 | c.5134A>G p.K1712E | Missense Mutation (SNP) | VAF 10/157 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ECPAS | c.371C>G p.P124R | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- GRIP1 | c.1607C>G p.T536S (on ENST00000359742 / NM_001379345.1; = p.T484S on NM_021150.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/153 reads (6%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.488); called by muse, mutect2
- HNRNPL | c.1415G>C p.C472S | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT tolerated (0.95); PolyPhen benign (0); called by muse, mutect2
- KCNIP3 | c.208T>A p.S70T | Missense Mutation (SNP) | VAF 16/142 reads (11%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.468); called by muse, mutect2
- KSR1 | c.270C>A p.C90* | Nonsense Mutation (SNP) | VAF 37/128 reads (29%) | called by muse, mutect2, varscan2
- LCT | c.5152G>A p.G1718S | Missense Mutation (SNP) | VAF 19/153 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.505); called by muse, mutect2, varscan2
- LTBP2 | c.3245A>T p.Y1082F | Missense Mutation (SNP) | VAF 29/324 reads (9%) | SIFT tolerated (0.47); PolyPhen benign (0.007); called by muse, mutect2
- MUC16 | c.29642A>T p.E9881V | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.961); called by muse, mutect2
- MYH2 | c.3357C>G p.A1119= | Splice Region (SNP) | VAF 29/256 reads (11%) | called by muse, mutect2
- NAPRT | c.638A>C p.H213P | Missense Mutation (SNP) | VAF 22/296 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- NCBP1 | c.635C>A p.P212H | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.852); called by muse, mutect2, varscan2
- NEB | c.12812C>A p.P4271H | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- ORC6 | c.394G>C p.D132H | Missense Mutation (SNP) | VAF 12/118 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.3); called by muse, mutect2, varscan2
- PCOLCE | c.383C>T p.T128I | Missense Mutation (SNP) | VAF 34/386 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.098); called by muse, mutect2
- PRKG1 | c.1132A>G p.I378V | Missense Mutation (SNP) | VAF 15/129 reads (12%) | SIFT tolerated (0.68); PolyPhen benign (0.019); called by muse, varscan2
- PTBP3 | c.155G>A p.R52K | Missense Mutation (SNP) | VAF 10/141 reads (7%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.916); called by muse, mutect2
- RTKN2 | c.1624G>T p.D542Y | Missense Mutation (SNP) | VAF 18/108 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); called by muse, mutect2, varscan2
- SEMA6C | c.955T>G p.F319V | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- TAS2R38 | c.293T>C p.L98P | Missense Mutation (SNP) | VAF 19/161 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.3); called by muse, mutect2, varscan2
- TRIM37 | c.1567G>C p.V523L | Missense Mutation (SNP) | VAF 29/119 reads (24%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- XRRA1 | c.1504G>A p.E502K | Missense Mutation (SNP) | VAF 43/188 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DRD2 | c.513C>A p.L171= | Silent (SNP) | VAF 14/238 reads (6%) | catalogued as COSV60759085; called by muse, mutect2
- EFCC1 | c.661C>T p.L221= | Silent (SNP) | VAF 24/135 reads (18%) | called by muse, mutect2, varscan2
- FJX1 | c.216C>A p.A72= | Silent (SNP) | VAF 6/22 reads (27%) | called by muse, mutect2, varscan2
- INPP5B | c.672C>T p.V224= | Silent (SNP) | VAF 19/79 reads (24%) | catalogued as rs766429146; called by muse, mutect2, varscan2
- MMP21 | c.72C>T p.P24= | Silent (SNP) | VAF 35/118 reads (30%) | catalogued as rs922019040, COSV100916683; called by muse, mutect2, varscan2
- MOCOS | c.2262A>G p.L754= | Silent (SNP) | VAF 12/190 reads (6%) | called by muse, mutect2
- NDOR1 | c.291C>T p.L97= | Silent (SNP) | VAF 16/114 reads (14%) | catalogued as rs750433403, COSV61287045; called by muse, mutect2, varscan2
- PACSIN1 | c.1230C>T p.D410= | Silent (SNP) | VAF 10/108 reads (9%) | catalogued as rs1035752345; called by muse, mutect2
- PANK4 | c.2007A>G p.A669= | Silent (SNP) | VAF 26/236 reads (11%) | called by muse, mutect2, varscan2
- SREBF2 | c.3048C>T p.G1016= | Silent (SNP) | VAF 15/95 reads (16%) | called by muse, mutect2, varscan2
- TARS1 | c.1968T>C p.C656= | Silent (SNP) | VAF 7/120 reads (6%) | catalogued as COSV54308311; called by muse, mutect2
- TMEM123 | c.9C>A p.L3= | Silent (SNP) | VAF 13/69 reads (19%) | called by muse, mutect2, varscan2
- AC092329.3 | c.-211-656A>G | Intron (SNP) | VAF 6/65 reads (9%) | catalogued as rs963015692, COSV68024692; called by muse, mutect2
- AL353804.7 | chrX:73848195 G>A | 5'Flank (SNP) | VAF 6/43 reads (14%) | catalogued as rs770221269; called by mutect2, varscan2
- F13A1 | c.1113-9157G>A | Intron (SNP) | VAF 8/74 reads (11%) | called by muse, varscan2
- GPT2 | c.1213-94T>C | Intron (SNP) | VAF 5/53 reads (9%) | called by muse, mutect2
- IQANK1 | c.175+3986G>A | Intron (SNP) | VAF 6/66 reads (9%) | catalogued as rs1554626965; called by muse, mutect2
- NPM1 | c.772-72G>A | Intron (SNP) | VAF 8/51 reads (16%) | catalogued as COSV51578664; called by muse, mutect2, varscan2
